Somatic mutation profile of tumor specimen TCGA-BK-A0CA-01A (aliquot TCGA-BK-A0CA-01A-21D-A272-09) from TCGA case TCGA-BK-A0CA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.3 years (22,378 days).
Specimen TCGA-BK-A0CA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbe5c52f-2f40-42de-b12f-709db8ea7c6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A0CA-10A (Blood Derived Normal), aliquot TCGA-BK-A0CA-10A-02D-A272-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc60c657-a147-44c4-8134-383f6c056228

The open-access MAF lists 54 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 37, Silent 11, Frame Shift Ins 3, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852428, CD123883, CM910133, COSV64269271; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 61/227 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAA1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs115896366; called by muse, mutect2, varscan2
- AHCYL2 | c.1135C>A p.L379I | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.364); catalogued as COSV61484809; called by muse, mutect2, varscan2
- ARHGAP6 | c.2533G>A p.G845S (on ENST00000337414 / NM_013427.3; = p.G642S on NM_013423.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1158111384, COSV57290474; called by muse, mutect2
- ARID1A | c.5365del p.A1789Pfs*17 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as COSV61370511; called by mutect2, pindel, varscan2
- AVPR1B | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs199633176, COSV65637644; called by muse, mutect2
- BMP15 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868942078, COSV53139709; called by muse, mutect2, varscan2
- CS | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV60831971; called by muse, mutect2, varscan2
- CSMD1 | c.6718G>A p.D2240N (on ENST00000520002; = p.D2239N on NM_033225.6) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs779137794, COSV59276564; called by muse, mutect2, varscan2
- DOCK6 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs371193621, COSV52948474; called by muse, mutect2, varscan2
- DYNC1H1 | c.8492G>A p.R2831H | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64133925; called by muse, mutect2, varscan2
- FAT2 | c.9610G>A p.V3204I | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.213); catalogued as rs140898888; called by muse, mutect2, varscan2
- FBXW7 | c.1427G>T p.S476I (on ENST00000281708 / NM_001349798.2; = p.S396I on NM_018315.5) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55890941, COSV55916432; called by muse, mutect2, varscan2
- FCGR3B | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54208662; called by muse, mutect2
- FIBIN | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV59412339; called by muse, mutect2, varscan2
- HLA-DRB5 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs758127925, COSV66612048; called by muse, mutect2, varscan2
- KHDC4 | c.877A>G p.M293V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs918763830, COSV64164428; called by muse, mutect2, varscan2
- MEGF8 | c.3384T>A p.S1128R (on ENST00000251268 / NM_001271938.2; = p.S1061R on NM_001410.3) | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52073656; called by muse, mutect2, varscan2
- MYO1H | c.320T>G p.M107R | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV60442496; called by muse, mutect2, varscan2
- NADSYN1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1356105492, COSV59809678; called by muse, mutect2, varscan2
- OR5B17 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV62159783; called by muse, mutect2, varscan2
- PCDHGB6 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs114361948, COSV54027199; called by muse, mutect2, varscan2
- PLAU | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234630259, COSV65640603; called by muse, mutect2, varscan2
- PROKR1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as COSV100375559, COSV58136445; called by muse, mutect2, varscan2
- SEC14L5 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs373434753; called by muse, mutect2, varscan2
- SLC25A13 | c.1406G>T p.S469I | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55703115, COSV55708551; called by muse, mutect2, varscan2
- SLCO4A1 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV53888954; called by muse, mutect2, varscan2
- SYT3 | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs757150838, COSV58895300; called by muse, mutect2, varscan2
- SYT9 | c.1330T>C p.Y444H | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV59614086; called by muse, mutect2, varscan2
- TTC4 | c.828G>T p.W276C | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64884300; called by muse, mutect2, varscan2
- TTN | c.99860A>T p.Y33287F (on ENST00000591111; = p.Y25863F on NM_003319.4) | Missense Mutation (SNP) | VAF 46/128 reads (36%) | PolyPhen benign (0.067); catalogued as COSV59861737; called by muse, mutect2, varscan2
- UNC5D | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54765601, COSV99772837; called by muse, varscan2
- ZHX1 | c.*2A>T | Splice Region (SNP) | VAF 47/151 reads (31%) | catalogued as COSV99933584; called by muse, mutect2, varscan2
- ZNF804A | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV56433533; called by muse, mutect2
- ZP1 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV53922900; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ARID1A | c.4689dup p.M1564Hfs*8 | Frame Shift Ins (INS) | VAF 16/101 reads (16%) | called by mutect2, pindel, varscan2
- BRD1 | c.2076dup p.R693Afs*177 (on ENST00000216267 / NM_001349940.1; = p.R693Afs*97 on NM_001304808.3) | Frame Shift Ins (INS) | VAF 57/165 reads (35%) | called by mutect2, pindel, varscan2
- POGZ | c.3192dup p.F1065Vfs*2 | Frame Shift Ins (INS) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- PTEN | c.920_923del p.E307Vfs*9 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | called by mutect2, pindel, varscan2
- RIMBP3 | c.3257C>T p.P1086L | Missense Mutation (SNP) | VAF 76/565 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AFAP1L1 | c.606G>A p.P202= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as rs769464611, COSV57043599; called by muse, mutect2, varscan2
- AP2A1 | c.2415G>A p.L805= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs1304768208, COSV100571084; called by muse, varscan2
- CUBN | c.4770C>T p.I1590= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs529907907, COSV64706616; called by muse, mutect2, varscan2
- FZD10 | c.957C>T p.F319= | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as COSV57471897; called by muse, mutect2, varscan2
- MCM2 | c.918C>T p.I306= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as COSV54031738; called by muse, mutect2, varscan2
- PCDHA13 | c.2037G>A p.S679= | Silent (SNP) | VAF 61/189 reads (32%) | catalogued as rs1223534357, COSV56474514; called by muse, mutect2, varscan2
- PLCH2 | c.339C>T p.D113= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs751401229, COSV53939163; called by muse, mutect2, varscan2
- RAD21 | c.1764G>A p.T588= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs200021994, COSV52055846; called by muse, mutect2, varscan2
- SYNGR2 | c.352C>T p.L118= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as COSV56744856; called by muse, mutect2, varscan2
- TICRR | c.4443C>T p.N1481= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs760061593, COSV51537281; called by muse, mutect2, varscan2
- TMEM132D | c.471C>T p.D157= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs139627769; called by muse, mutect2, varscan2
